Surgical pathology report (de-identified scan), TCGA case TCGA-57-1583, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1583-01A (Primary Tumor).

[page 1 of 2]
TCGA-57-1583

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Ovary and fallopian tube, left, salpingo-oophorectomy:

Papillary serous adenocarcinoma

Grade 3

Tumor completely replaces specimen with surface involvement

Lymphovascular space invasion, not identified.

Left fallopian tube, not identified.

B. Lymph nodes, left pelvic, dissection:

Metastatic serous adenocarcinoma involving one of two nodes examined (1/2).

C. Omentum, omentectomy:

Inflammation and mesothelial reaction, negative for neoplasm.

Omental lymph node, negative for neoplasm, one node examined (0/1).

D. Uterus, right ovary and fallopian tube, hysterectomy and salpingo-oophorectomy:

Cervix, no pathologic change.

Endometrium, inactive pattern.

Myometrium, no pathologic change.

Right ovary, no pathologic change.

Right fallopian tube, no pathologic change.

Staging Sheet #3

pTNM staging: T3c, N1, MX (FIGO: IIIC).

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Pelvic mass.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Left tube and ovary

B. Left pelvic

C. Omentum

D. Uterus, cervix, and right tube and ovary

SPECIMEN DATA

GROSS DESCRIPTION:

A. Received in formalin labeled [redacted] and #1 is a 12.7 x 10.5 x 5.4 cm, tan-red mass, with attached adipose tissue. The cut surface consists of a 6.0 x 4.0 x 2.0 cm cyst. The remainder of the cut surface consists of tan-pink to white soft tissue. No obvious ovarian parenchyma is identified. An obvious fallopian tube is not identified. The specimen is serially sectioned and a representative section is submitted for frozen section and the frozen section residue is submitted in block 1. Additional representative sections are submitted as labeled: Blocks 2 and 3 cystic area; blocks 4-10 random mass. The blocks are labeled [redacted]. Also received in the same container are three orange cassettes labeled [redacted] and a yellow and green cassettes labeled [redacted] for genomic research study.

B. Received in formalin labeled [redacted]

and #2 left pelvic is a 2.8 x 1.9 x 0.8 cm, irregular, tan-yellow, firm tissue, consistent with possible lymph

[page 2 of 2]
node. The specimen is bisected and submitted in its entirety in two cassettes labeled :

C. Received in formalin labeled and omentum is a 10.1 x 9.2 x 2.1 cm aggregate of fibroadipose tissue, consistent with omentum. The cut surface consists of predominantly yellow lobulated adipose tissue with a minimal amount of gray-white fibrous tissue. No lesions are identified. The specimen is serially sectioned and representative sections are submitted in four cassettes labeled

D. Received in formalin labeled and uterus, cervix, and right tube and ovary is a 92 gm previously opened hysterectomy specimen, consisting of a 4.1 x 3.5 x 2.6 cm uterine body and a 3.6 x 3.1 x 2.5 cm cervix, with attached right ovary and fallopian tube. The serosa is smooth and tan-pink. The ectocervix is smooth and gray-white with a 0.2 cm slit like os and a minimal amount of attached vaginal mucosa. The endocervical canal is glistening tan and 2.4 cm in length. The endometrial cavity is 1.8 cm from cornu to cornu and 2.7 cm in length. The endometrium is glistening, tan, and averages 0.1 cm in thickness. The myometrium is trabeculated, tan-pink, and ranges from 1.9 cm to 2.3 cm in thickness. The 1.9 x 0.9 x 0.5 cm right ovary has a lobulated, tan-yellow outer surface. The cut surface is tan-pink with a 0.3 cm smooth lined cyst and gray-white corpora albicans. The attached 3.9 x 0.5 cm fimbriated right fallopian tube has a tan-pink serosa with two paratubal cysts, averaging 0.2 cm in greatest dimension and a pinpoint lumen. The specimen is serially sectioned and representative sections are submitted as labeled: Block 1 anterior cervix; 2 posterior cervix; 3 anterior endomyometrium with serosa; 4 and 5 posterior endomyometrium with serosa, bisected; block 6 right ovary and fallopian tube. The blocks are labeled

Source: NCI Genomic Data Commons file e2b618d6-7a12-4b24-87a8-8a117284bad6 (TCGA-57-1583.B899B485-621F-46DF-8BDA-97B0FBE10B6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).